MMRF case MMRF_2204 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/703d6cbd-191b-48d3-8a6d-f7b860a9a634

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Dead; Days to death: 616 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.6 years (30,186 days); Days to last known disease status: 616 days (1.7 years); Days to last follow up: 616 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 109 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 232 days; Days to treatment end: 359 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 235 days; Days to treatment end: 394 days (1.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 375 days (1.0 years); Days to treatment end: 394 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 616.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 2): M Protein 0.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 88.9 mg/dL; Immunoglobulin G 2 g/L; Immunoglobulin A 15.1 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 7.5 g/dL; Glucose 6.44 mmol/L.
- Day 93 (ECOG 2): M Protein 1.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 43.7 mg/dL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 26 g/L; Total Protein 7.1 g/dL; Glucose 5.89 mmol/L.
- Day 155 (ECOG 2): Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 28 g/L; Total Protein 6.9 g/dL; Glucose 5.67 mmol/L.
- Day 249 (ECOG 2): M Protein 1.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 255 mg/dL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 371 ×10⁹/L; Creatinine 327 µmol/L; Blood Urea Nitrogen 17.5 mmol/L; Calcium 2.35 mmol/L; Albumin 31 g/L; Total Protein 7.6 g/dL; Glucose 6.71 mmol/L.
- Day 361 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 111 mg/dL; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 230 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.48 mmol/L; Albumin 34 g/L; Total Protein 8.4 g/dL; Glucose 5.56 mmol/L.
- Day 443 (ECOG 2): Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.35 mmol/L; Albumin 27 g/L; Total Protein 9.4 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -9: Weight: 94 kg; Height: 180 cm.

Biospecimens (3 samples)
- Sample MMRF_2204_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2204_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
- Sample MMRF_2204_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 443 days (1.2 years).
